Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L2, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L2-01A (Primary Tumor).

ICD O-3
Tumor Adrenal Cortical of unknown/
uncertain behavior 8370/1
Site: Adrenal Gland, Cortex C74.2
QW 2/6/13

Procedure: L adrenalectomy, pararenal adipose tissue

Gross description: 18 x 9.5 x 5.5cm, 403g

Diagnosis: adrenocortical carcinoma, mitotic rate 6 per 10 hpf

Reference Pathology: none

Per NCI, case may ship as long
as it is ACC (regardless of
stated behavior). BCR

Spouse - if case passes we will
request more path - may not ship if not
malignant.

Criteria	hw 4/14/13	Yes	No

Source: NCI Genomic Data Commons file b7bd5c4f-22d9-45d2-bc37-7c98600b795d (TCGA-OR-A5L2.A3E8E475-D5A7-4A4C-AA1D-3B3AE50F572B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).